Somatic mutation profile of tumor specimen MP2PRT-PATTGH-TMP1-A (aliquot MP2PRT-PATTGH-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATTGH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,099 days).
Specimen MP2PRT-PATTGH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa0720ce-9a1c-4c97-a358-d942c7c8a8c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTGH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTGH-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36261c65-59a7-4340-bcfd-159135cea415

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 5, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR6C75 | c.729G>C p.M243I | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as COSV58553710; called by muse, mutect2
- PARP3 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 36/688 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV67168366; called by muse, mutect2
- SPHKAP | c.2489C>G p.S830C | Missense Mutation (SNP) | VAF 20/464 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV60872824; called by muse, mutect2
- ZNF609 | c.1211G>C p.G404A | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.048); catalogued as rs1175076920; called by muse, mutect2
- BX255925.3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.955); called by muse, mutect2
- CCDC191 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- CRAMP1 | c.2033G>A p.W678* | Nonsense Mutation (SNP) | VAF 16/587 reads (3%) | called by muse, mutect2
- EXOSC7 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- GNAI1 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- MAP1LC3B | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 54/228 reads (24%) | called by muse, varscan2
- MCC | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 20/625 reads (3%) | called by muse, mutect2
- MTMR1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 34/725 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2
- NR3C2 | c.1409C>G p.S470* | Nonsense Mutation (SNP) | VAF 11/350 reads (3%) | called by muse, mutect2
- RIMBP2 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 36/907 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SUGP1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- ADGRA3 | c.3126C>T p.F1042= | Silent (SNP) | VAF 28/584 reads (5%) | catalogued as COSV51563351; called by muse, mutect2
- PARM1 | c.240C>T p.N80= | Silent (SNP) | VAF 15/502 reads (3%) | catalogued as rs1213388344; called by muse, mutect2
- PPP3CC | c.558C>G p.L186= | Silent (SNP) | VAF 21/478 reads (4%) | called by muse, mutect2
- ANXA8 | c.207+138G>A | Intron (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2
